Somatic mutation profile of tumor specimen ALCH-AFFH-TTP1-A (aliquot ALCH-AFFH-TTP1-A-1-0-D-A667-36) from ALCHEMIST case ALCH-AFFH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.8 years (25,499 days).
Specimen ALCH-AFFH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7934705b-4500-4aa2-b33a-dc5203c425c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFFH-NB1-A (Blood Derived Normal), aliquot ALCH-AFFH-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30c23caa-55f3-4d53-a062-079686697c43

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 9, Nonsense Mutation 2, In Frame Del 2, Intron 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 96/549 reads (17%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- CHPF2 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV50396629; called by muse, mutect2, varscan2
- COLGALT1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs757122399; called by muse, mutect2, varscan2
- CPN1 | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs746171499; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs754135731; called by mutect2, varscan2*
- DIS3 | c.1999_2000del p.M667Vfs*13 | Frame Shift Del (DEL) | VAF 26/196 reads (13%) | catalogued as rs1428278025; called by mutect2, pindel, varscan2
- GSDMC | c.1073T>A p.L358Q | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99416417; called by muse, mutect2, varscan2
- MTOR | c.2319G>T p.E773D | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.121); catalogued as COSV63878500; called by muse, mutect2, varscan2
- NEDD4 | c.110G>T p.R37I | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); catalogued as COSV59058860; called by muse, mutect2, varscan2
- NEXN | c.1620G>A p.M540I | Missense Mutation (SNP) | VAF 58/434 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV53931892; called by muse, mutect2, varscan2
- PLA2G4F | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.57); catalogued as rs375162581; called by muse, mutect2
- PLXND1 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1362474229, COSV60711652; called by muse, mutect2
- SNAP47 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1209967041; called by muse, mutect2, varscan2
- STEAP3 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs771999099, COSV61529103; called by mutect2, varscan2
- TAAR6 | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.033); catalogued as rs745510373; called by muse, mutect2, varscan2
- TGIF2LX | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52213479; called by muse, mutect2, varscan2
- ADCK2 | c.1047T>G p.I349M | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ADRA2B | c.599A>C p.K200T | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.093); called by mutect2, varscan2
- ARID2 | c.2419A>T p.N807Y | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CPT1C | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- FIG4 | c.2110A>C p.K704Q | Missense Mutation (SNP) | VAF 93/636 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- GAD2 | c.971A>G p.Q324R | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GGA1 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- OSER1 | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLA2 | c.444C>A p.Y148* | Nonsense Mutation (SNP) | VAF 37/315 reads (12%) | called by muse, mutect2, varscan2
- SLC35F4 | c.1505C>A p.P502H (on ENST00000339762 / NM_001352015.2; = p.P466H on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/426 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- TARDBP | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 36/422 reads (9%) | called by muse, mutect2
- CD109 | c.2742G>A p.L914= | Silent (SNP) | VAF 74/414 reads (18%) | catalogued as COSV54647749; called by muse, mutect2, varscan2
- EEF1B2 | c.537A>G p.P179= | Silent (SNP) | VAF 22/203 reads (11%) | called by muse, mutect2, varscan2
- EIF3B | c.276G>T p.L92= | Silent (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- EYS | c.1950G>A p.A650= | Silent (SNP) | VAF 93/675 reads (14%) | catalogued as rs565864295, COSV65458524; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- HELZ2 | c.1572G>T p.A524= | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2
- MROH9 | c.111C>A p.G37= | Silent (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- PDIK1L | c.852G>T p.L284= | Silent (SNP) | VAF 19/267 reads (7%) | called by muse, mutect2
- PRMT9 | c.442T>C p.L148= | Silent (SNP) | VAF 48/346 reads (14%) | called by muse, mutect2, varscan2
- UBQLN3 | c.255C>T p.L85= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as rs1451577540; called by muse, mutect2, varscan2
- FER1L4 | n.3548C>T | RNA (SNP) | VAF 14/77 reads (18%) | catalogued as rs759791138; called by muse, mutect2, varscan2
- INO80B | c.59-105C>T | Intron (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
